Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6YZ, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6YZ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

ICD-O-3
Fibromyxosarcoma 8811/3
Site @ Groin NOS C49.5
JW 8/9/13

....

Clinical Diagnosis & History:

Right thigh mass 9.9 x 6.8 x 6 cm, myxofibrosarcoma vs. LPS.

Specimens Submitted:

1: SP: Radical resection of right groin sarcoma

DIAGNOSIS:

1. SOFT TISSUE, RIGHT GROIN; RADICAL RESECTION:
- HIGH GRADE MYXOFIBROSARCOMA.
- TUMOR MEASURES 9.1 CM GREATEST DIMENSION, INVOLVES SUBCUTANEOUS FIBROADIPOSE TISSUE, AND SHOWS ABOUT 10% NECROSIS (MICROSCOPIC ESTIMATE).
- TUMOR IS 0.7 CM FROM DEEP MARGIN (OTHER MARGINS WIDELY CLEAR).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received in a fresh state, labeled as "radical resection of right groin sarcoma", and consists of a portion of soft tissue measuring 22 x 12 x 8 cm. Grossly unremarkable skin ellipse without scar measuring 22 x 7.2 cm is attached on the superficial aspect. The specimen is oriented with a short stitch for the superior, and with a long stitch for lateral. The specimen is inked: Lateral -- green, medial -- blue, superior -- red, inferior -- yellow, deep -- black. Sectioning reveals a well-circumscribed vaguely multinodular tan-yellow solid fleshy mass measuring 9.1 x 7.5 x 6.5 cm in the deep subcutaneous tissue. The tumor grossly does not involve deeply attached skeletal muscle. There is a 4.5 x 3 x 3 cm myxoid area in the center of the mass. Hemorrhage and necrosis (less than 5%) are noted. The tumor is 0.7 cm from deep margin, 1.5 cm from lateral margin, 1.5 cm from the medial margin, 7.2 cm from superior margin,

** Continued on next page **

[page 2 of 2]
----- Page 2 of 2
and 8.0 cm from inferior margin. Overlying skin is not involved. The specimen is photographed. TPS is taken from the non-myxoid part. Representative sections are submitted.

Summary of sections:

S -- superior margin
I -- inferior margin
M -- medial margin
L -- lateral margin
D -- deep margin
SKIN -- skin
T -- tumor, solid area
TMYX -- tumor, myxoid area

Summary of Sections:

Part 1: SP: Radical resection of right groin sarcoma

Block	Sect.	Site	PCs
4		d	4
1		i	1
2		l	2
2		m	2
1		s	1
1		skin	1
8		t	8
3		tmyx	3

** End of Report **

May/Specimen Primary		☒

DATE: 7/23/13

Source: NCI Genomic Data Commons file 85aec9fa-684c-4635-8f45-cc59bcf465a5 (TCGA-DX-A6YZ.F9C09BF0-27C8-4EA2-AE3C-EA9CF1D5CAF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).